Somatic mutation profile of tumor specimen ALCH-B1RQ-TTP1-A (aliquot ALCH-B1RQ-TTP1-A-1-0-D-A76B-36) from ALCHEMIST case ALCH-B1RQ, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 71.9 years (26,248 days).
Specimen ALCH-B1RQ-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cc91c98-9dcf-45c8-96e9-e1fbc5cc9bc0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B1RQ-NB1-A (Blood Derived Normal), aliquot ALCH-B1RQ-NB1-A-1-0-D-A76B-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6e2fb789-7d4f-44f0-9fc9-f6bbbf7366e6

The open-access MAF lists 240 somatic variants for this specimen: 171 protein-altering or splice-affecting, 44 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 150, Silent 44, Nonsense Mutation 13, Intron 11, RNA 8, 3'UTR 4, Splice Site 3, Splice Region 2, Frame Shift Del 2, 5'UTR 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 27/240 reads (11%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MTOR | c.5662T>A p.F1888I | Missense Mutation (SNP) | VAF 19/313 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63868094, COSV63868329, COSV63874983; called by muse, mutect2
- ABCC11 | c.1891G>T p.G631C | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62325395; called by muse, mutect2
- ABCC8 | c.3641G>T p.R1214L | Missense Mutation (SNP) | VAF 40/397 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CM981880; called by muse, mutect2, varscan2
- ABCG5 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 19/220 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.916); catalogued as rs1281965785; called by muse, mutect2
- AC092143.1 | c.1218C>A p.Y406* | Nonsense Mutation (SNP) | VAF 32/390 reads (8%) | catalogued as COSV100205914; called by muse, mutect2
- ACTR8 | c.1194T>A p.F398L | Missense Mutation (SNP) | VAF 11/109 reads (10%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.605); catalogued as COSV51637162; called by muse, mutect2, varscan2
- ANK2 | c.5927C>A p.S1976Y | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV52170624; called by muse, mutect2
- ANKRD27 | c.1273G>A p.D425N | Missense Mutation (SNP) | VAF 20/276 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.912); catalogued as rs1382422902; called by muse, mutect2
- ARAP3 | c.1286C>A p.S429Y | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as COSV53350098, COSV53355177; called by muse, mutect2
- ASXL3 | c.3059G>T p.G1020V | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV52466818; called by muse, mutect2, varscan2
- ATP6V0D2 | c.29A>G p.N10S | Missense Mutation (SNP) | VAF 22/276 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.97); catalogued as rs757214740; called by muse, mutect2
- BPIFB2 | c.956G>T p.R319L | Missense Mutation (SNP) | VAF 16/97 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs746477434; called by muse, mutect2, varscan2
- C4orf54 | c.3637C>A p.Q1213K | Missense Mutation (SNP) | VAF 17/191 reads (9%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.497); catalogued as rs1161687225; called by muse, mutect2
- CDCA7 | c.880G>T p.G294C (on ENST00000347703 / NM_145810.3; = p.G373C on NM_031942.5) | Missense Mutation (SNP) | VAF 14/280 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60721390; called by muse, mutect2
- CFAP74 | c.2161G>A p.E721K | Missense Mutation (SNP) | VAF 35/407 reads (9%) | SIFT tolerated (0.63); PolyPhen benign (0.043); catalogued as COSV54565132; called by muse, mutect2
- CHRNA2 | c.259C>T p.R87C | Missense Mutation (SNP) | VAF 24/507 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.052); catalogued as rs778191765; ClinVar: uncertain significance; called by muse, mutect2
- DPYSL5 | c.596C>T p.A199V | Missense Mutation (SNP) | VAF 5/73 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.198); catalogued as COSV56509416; called by muse, mutect2
- DSG3 | c.2489C>A p.S830Y | Missense Mutation (SNP) | VAF 49/473 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1219046752, COSV57124757; called by muse, mutect2, varscan2
- EPHA5 | c.210G>T p.M70I | Missense Mutation (SNP) | VAF 14/270 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.003); catalogued as COSV99901014; called by muse, mutect2
- F2R | c.242A>T p.Q81L | Missense Mutation (SNP) | VAF 18/241 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.026); catalogued as COSV59930077; called by muse, mutect2
- FAM183A | c.148A>G p.R50G | Missense Mutation (SNP) | VAF 22/296 reads (7%) | SIFT tolerated (0.36); PolyPhen probably damaging (0.996); catalogued as rs1176641000; called by muse, mutect2
- FAM47B | c.90C>A p.F30L | Missense Mutation (SNP) | VAF 12/187 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.029); catalogued as COSV61456092, COSV61456316; called by muse, mutect2
- FLNC | c.5126C>A p.P1709H | Missense Mutation (SNP) | VAF 26/318 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV57956233; called by muse, mutect2
- FRYL | c.2471A>G p.Y824C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs544935208, COSV99977080; called by muse, mutect2, varscan2
- GALNS | c.911G>A p.G304D | Missense Mutation (SNP) | VAF 32/428 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as CM1314336; called by muse, mutect2
- ITGAE | c.2329G>A p.E777K | Missense Mutation (SNP) | VAF 26/382 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0.121); catalogued as COSV53994671; called by muse, mutect2
- KMT2C | c.4247C>T p.S1416L | Missense Mutation (SNP) | VAF 21/185 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.619); catalogued as rs369143780, COSV100068774, COSV51460385; called by muse, mutect2, varscan2
- LEF1 | c.1076A>G p.H359R | Missense Mutation (SNP) | VAF 25/203 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1319328618; called by muse, mutect2, varscan2
- MAPKAPK3 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 13/143 reads (9%) | SIFT deleterious (0.05); PolyPhen benign (0.057); catalogued as COSV63597551; called by muse, mutect2
- MEX3D | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 11/164 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752546270; called by muse, mutect2
- MGAM | c.4885G>T p.E1629* | Nonsense Mutation (SNP) | VAF 27/216 reads (13%) | catalogued as COSV72075252; called by muse, mutect2, varscan2
- MST1R | c.2582C>G p.P861R | Missense Mutation (SNP) | VAF 22/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV56570787; called by muse, mutect2
- MTUS2 | c.562G>A p.G188R | Missense Mutation (SNP) | VAF 11/252 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.046); catalogued as rs796307345, COSV70917931, COSV70922434; called by muse, mutect2
- MTUS2 | c.1918G>T p.V640L | Missense Mutation (SNP) | VAF 18/232 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70914771; called by muse, mutect2
- MUC16 | c.35168C>T p.P11723L | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.028); catalogued as COSV67480810; called by muse, mutect2, varscan2
- NEGR1 | c.589C>A p.Q197K | Missense Mutation (SNP) | VAF 16/222 reads (7%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.775); catalogued as COSV100166231; called by muse, mutect2
- NKD2 | c.259G>T p.A87S | Missense Mutation (SNP) | VAF 22/273 reads (8%) | SIFT tolerated (0.9); PolyPhen benign (0.015); catalogued as rs769021504; called by muse, mutect2
- NOTCH3 | c.3074C>A p.P1025H | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.841); catalogued as rs1401870864, COSV54630897, COSV54634871; called by muse, mutect2
- OR56A3 | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 11/282 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.702); catalogued as COSV61568824; called by muse, mutect2
- PKHD1 | c.10372A>G p.T3458A | Missense Mutation (SNP) | VAF 11/100 reads (11%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs760790892; called by muse, mutect2, varscan2
- PTPN14 | c.856G>T p.E286* | Nonsense Mutation (SNP) | VAF 35/247 reads (14%) | catalogued as COSV65282974; called by muse, mutect2, varscan2
- SAMD9 | c.1609G>T p.G537W | Missense Mutation (SNP) | VAF 16/248 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV66076069; called by muse, mutect2
- SLC17A8 | c.1662T>G p.N554K | Missense Mutation (SNP) | VAF 16/176 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.065); catalogued as COSV60125499; called by muse, mutect2
- SLC2A10 | c.1025C>A p.P342H | Missense Mutation (SNP) | VAF 62/515 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV100826380; called by muse, mutect2, varscan2
- STRN4 | c.839A>G p.D280G | Missense Mutation (SNP) | VAF 21/196 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.202); catalogued as rs1394226837; called by muse, mutect2, varscan2
- SYNE2 | c.2518G>T p.V840F | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT tolerated (0.32); PolyPhen benign (0.096); catalogued as COSV59942231; called by muse, mutect2
- TAS2R38 | c.436G>T p.G146C | Missense Mutation (SNP) | VAF 21/274 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.628); catalogued as rs1201607264; called by muse, mutect2
- TCEANC2 | c.29G>A p.R10K | Missense Mutation (SNP) | VAF 26/246 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.001); catalogued as COSV99328572; called by muse, mutect2
- TLE1 | c.1642G>C p.G548R | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1462335117; called by muse, mutect2
- TRIM58 | c.849G>T p.R283S | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.109); catalogued as COSV100825368, COSV63568907; called by muse, mutect2, varscan2
- ZEB2 | c.3526C>A p.P1176T | Missense Mutation (SNP) | VAF 12/297 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); catalogued as COSV57955814; called by muse, mutect2
- ZFHX4 | c.3797C>G p.T1266R | Missense Mutation (SNP) | VAF 28/414 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51467227; called by muse, mutect2
- ZNF615 | c.1241G>C p.C414S | Missense Mutation (SNP) | VAF 14/162 reads (9%) | SIFT tolerated (0.86); PolyPhen benign (0); catalogued as COSV65034210; called by muse, mutect2
- ZNF648 | c.350C>A p.P117Q | Missense Mutation (SNP) | VAF 62/471 reads (13%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); catalogued as COSV60572805; called by muse, mutect2, varscan2
- ZNF792 | c.1133G>T p.R378L | Missense Mutation (SNP) | VAF 20/293 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV68694018; called by muse, mutect2
- ABCC9 | c.1453C>A p.L485I | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- ACCSL | c.709G>T p.V237L | Missense Mutation (SNP) | VAF 18/346 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.759); called by muse, mutect2
- ACTL8 | c.224G>T p.W75L | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ADCY5 | c.1841T>A p.L614Q | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADGRE1 | c.2382-1G>T p.X794_splice | Splice Site (SNP) | VAF 7/65 reads (11%) | called by muse, mutect2, varscan2
- AGFG2 | c.458G>T p.G153V | Missense Mutation (SNP) | VAF 21/334 reads (6%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.982); called by muse, mutect2
- ANK2 | c.10367del p.G3456Afs*20 | Frame Shift Del (DEL) | VAF 13/139 reads (9%) | called by mutect2, pindel, varscan2
- ANKLE1 | c.95C>A p.A32D | Missense Mutation (SNP) | VAF 14/158 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP6V1G3 | c.142A>G p.R48G | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.875); called by muse, mutect2, varscan2
- C18orf25 | c.544A>G p.R182G | Missense Mutation (SNP) | VAF 33/369 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); called by muse, mutect2
- CC2D1A | c.2060C>T p.P687L | Missense Mutation (SNP) | VAF 28/310 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2
- CCDC168 | c.9197A>G p.H3066R | Missense Mutation (SNP) | VAF 5/66 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.099); called by muse, mutect2
- CDK12 | c.73T>C p.S25P | Missense Mutation (SNP) | VAF 30/259 reads (12%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CFAP69 | c.850G>T p.E284* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | called by muse, mutect2
- CHAF1A | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 36/442 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); called by muse, mutect2
- CLEC12B | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 24/266 reads (9%) | SIFT tolerated (0.69); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- CLUL1 | c.319G>T p.E107* | Nonsense Mutation (SNP) | VAF 37/441 reads (8%) | called by muse, mutect2
- COL20A1 | c.559T>C p.S187P | Missense Mutation (SNP) | VAF 16/217 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL2A1 | c.1741C>A p.P581T | Missense Mutation (SNP) | VAF 31/479 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.241); called by muse, mutect2
- COL9A2 | c.829G>T p.G277W | Missense Mutation (SNP) | VAF 27/397 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPA6 | c.1086C>A p.Y362* | Nonsense Mutation (SNP) | VAF 22/325 reads (7%) | called by muse, mutect2
- CPLANE1 | c.8725G>T p.A2909S | Missense Mutation (SNP) | VAF 21/177 reads (12%) | SIFT tolerated (0.22); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CTPS2 | c.1645G>T p.G549W | Missense Mutation (SNP) | VAF 22/312 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- DAAM2 | c.2609C>A p.A870D | Missense Mutation (SNP) | VAF 15/139 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- DGKI | c.541C>A p.L181M | Missense Mutation (SNP) | VAF 28/512 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.029); called by muse, mutect2
- DIO2 | c.324G>T p.E108D | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- DIXDC1 | c.226G>T p.G76C | Missense Mutation (SNP) | VAF 14/305 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2
- DLG5 | c.3004C>T p.Q1002* | Nonsense Mutation (SNP) | VAF 21/179 reads (12%) | called by muse, mutect2, varscan2
- DNAH9 | c.4516G>T p.D1506Y | Missense Mutation (SNP) | VAF 32/443 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- DOCK2 | c.2563G>A p.D855N | Missense Mutation (SNP) | VAF 16/402 reads (4%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.984); called by muse, mutect2
- DPPA5 | c.39G>T p.W13C | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- F2R | c.243A>T p.Q81H | Missense Mutation (SNP) | VAF 18/235 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.001); called by muse, mutect2
- FANCA | c.3563A>C p.H1188P | Missense Mutation (SNP) | VAF 28/490 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.087); called by muse, mutect2
- FMR1NB | c.123C>A p.S41R | Missense Mutation (SNP) | VAF 18/356 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.414); called by muse, mutect2
- GAA | c.952A>G p.M318V | Missense Mutation (SNP) | VAF 14/171 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); called by muse, mutect2
- GABRA1 | c.611G>T p.R204L | Missense Mutation (SNP) | VAF 50/382 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GABRG2 | c.970A>G p.T324A (on ENST00000361925 / NM_001375343.1; = p.T284A on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GDF6 | c.110T>A p.L37Q | Missense Mutation (SNP) | VAF 38/238 reads (16%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); called by muse, varscan2
- GEN1 | c.1804C>A p.Q602K | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.92); PolyPhen benign (0.027); called by mutect2, varscan2
- GLIS3 | c.88G>T p.A30S | Missense Mutation (SNP) | VAF 47/613 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.01); called by muse, mutect2
- GPR101 | c.945C>A p.D315E | Missense Mutation (SNP) | VAF 8/166 reads (5%) | SIFT tolerated, low confidence (0.96); PolyPhen benign (0.001); called by muse, mutect2
- GRIP2 | c.410C>A p.P137Q (on ENST00000619221; = p.P40Q on NM_001080423.4) | Missense Mutation (SNP) | VAF 13/188 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2
- GUCY1A2 | c.1304G>T p.G435V | Missense Mutation (SNP) | VAF 19/191 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HEATR1 | c.6160G>T p.V2054L | Missense Mutation (SNP) | VAF 13/301 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.469); called by muse, mutect2
- HMCN2 | c.11975C>A p.P3992Q | Missense Mutation (SNP) | VAF 21/142 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.845); called by muse, mutect2, varscan2
- HTR1F | c.422G>T p.G141V | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.246); called by muse, mutect2
- HTR4 | c.587G>T p.C196F | Missense Mutation (SNP) | VAF 43/295 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IGLC7 | c.305C>A p.P102H | Missense Mutation (SNP) | VAF 31/282 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.544); called by muse, varscan2
- IL13RA1 | c.279G>T p.R93S | Missense Mutation (SNP) | VAF 12/242 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.035); called by muse, mutect2
- IL36G | c.160G>T p.V54F | Missense Mutation (SNP) | VAF 8/100 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); called by muse, mutect2
- INTS9 | c.510G>T p.K170N | Missense Mutation (SNP) | VAF 20/193 reads (10%) | SIFT tolerated (0.49); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IQCD | c.812G>T p.R271L | Missense Mutation (SNP) | VAF 17/258 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.954); called by muse, mutect2
- IQGAP2 | c.734C>A p.T245N | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2
- KDM7A | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.092); called by muse, mutect2, varscan2
- KHK | c.105G>C p.Q35H | Missense Mutation (SNP) | VAF 25/374 reads (7%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.618); called by muse, mutect2
- KLHL18 | c.649G>T p.G217C | Missense Mutation (SNP) | VAF 17/266 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.015); called by muse, mutect2
- LOXHD1 | c.3601G>A p.G1201S | Missense Mutation (SNP) | VAF 16/208 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRFN5 | c.715G>T p.G239* | Nonsense Mutation (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- LRRC10B | c.62G>C p.S21T | Missense Mutation (SNP) | VAF 5/100 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.037); called by muse, mutect2
- LRRC53 | c.226G>A p.A76T | Missense Mutation (SNP) | VAF 24/403 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.818); called by muse, mutect2
- LRRC7 | c.920C>A p.P307H (on ENST00000651989 / NM_001370785.2; = p.P274H on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- MAB21L2 | c.253G>A p.V85I | Missense Mutation (SNP) | VAF 17/285 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); called by muse, mutect2
- MAGEB18 | c.295G>T p.A99S | Missense Mutation (SNP) | VAF 24/360 reads (7%) | SIFT tolerated (0.57); PolyPhen benign (0.012); called by muse, mutect2
- MAGI2 | c.1514T>A p.V505E | Missense Mutation (SNP) | VAF 31/300 reads (10%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MGAM2 | c.488C>A p.A163D | Missense Mutation (SNP) | VAF 13/200 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.018); called by muse, mutect2
- MTX3 | c.426G>T p.M142I | Missense Mutation (SNP) | VAF 36/388 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.065); called by muse, mutect2
- MUC5B | c.13145C>A p.P4382H | Missense Mutation (SNP) | VAF 36/478 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2
- MUC5B | c.13322C>A p.S4441Y | Missense Mutation (SNP) | VAF 38/445 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.005); called by muse, mutect2
- MVB12B | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 12/169 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.031); called by muse, mutect2
- MYDGF | c.173G>C p.G58A | Missense Mutation (SNP) | VAF 11/89 reads (12%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYH11 | c.2431C>A p.Q811K | Missense Mutation (SNP) | VAF 11/170 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.034); called by muse, mutect2
- MYO7B | c.2683G>T p.G895C | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- NBPF7 | n.870G>T | Splice Region (SNP) | VAF 12/282 reads (4%) | called by muse, mutect2
- NEB | c.11260G>T p.A3754S | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.498); called by muse, mutect2
- NLRP4 | c.2290G>T p.D764Y | Missense Mutation (SNP) | VAF 22/266 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); called by muse, mutect2
- NONO | c.1156C>A p.Q386K | Missense Mutation (SNP) | VAF 16/407 reads (4%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.678); called by muse, mutect2
- OR2T11 | c.721C>A p.H241N | Missense Mutation (SNP) | VAF 24/178 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- OR2Y1 | c.766T>C p.Y256H | Missense Mutation (SNP) | VAF 11/138 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2
- OR4K2 | c.701C>G p.S234C | Missense Mutation (SNP) | VAF 20/393 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- OR6K6 | c.641G>T p.S214I (on ENST00000368144; = p.S190I on NM_001005184.1) | Missense Mutation (SNP) | VAF 15/149 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.37); called by muse, mutect2, varscan2
- PCDHA7 | c.1577A>T p.E526V | Missense Mutation (SNP) | VAF 81/493 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGA3 | c.1139G>T p.G380V | Missense Mutation (SNP) | VAF 11/141 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- PDZD4 | c.586G>T p.V196L | Missense Mutation (SNP) | VAF 46/334 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLCE1 | c.640G>T p.G214* | Nonsense Mutation (SNP) | VAF 6/118 reads (5%) | called by muse, mutect2
- PLEC | c.5179del p.A1727Hfs*126 (on ENST00000322810 / NM_201380.4; = p.A1617Hfs*126 on NM_000445.5) | Frame Shift Del (DEL) | VAF 32/250 reads (13%) | called by mutect2, pindel, varscan2
- PPP1R3G | c.433G>A p.V145M | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.791); called by muse, mutect2, varscan2
- RBM10 | c.2056G>T p.E686* | Nonsense Mutation (SNP) | VAF 30/360 reads (8%) | called by muse, mutect2
- RBP3 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- RPGRIP1 | c.989G>T p.R330M | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.818); called by muse, mutect2
- RYR2 | c.5722C>A p.L1908I | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.034); called by muse, mutect2
- SDHA | c.1795-7G>T | Splice Region (SNP) | VAF 52/651 reads (8%) | called by muse, mutect2
- SLC1A3 | c.994G>T p.V332F | Missense Mutation (SNP) | VAF 62/492 reads (13%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.681); called by muse, mutect2, varscan2
- SLC9A7 | c.190G>T p.E64* | Nonsense Mutation (SNP) | VAF 8/196 reads (4%) | called by muse, mutect2
- SPOCK3 | c.484-1G>T p.X162_splice | Splice Site (SNP) | VAF 7/98 reads (7%) | called by muse, mutect2
- SRCAP | c.6730-1G>T p.X2244_splice | Splice Site (SNP) | VAF 24/326 reads (7%) | called by muse, mutect2
- TAF1L | c.2492A>C p.Y831S | Missense Mutation (SNP) | VAF 40/492 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TBC1D23 | c.1767T>A p.D589E (on ENST00000394144 / NM_001199198.3; = p.D574E on NM_018309.5) | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.991); called by muse, mutect2
- TECTA | c.3247T>C p.C1083R | Missense Mutation (SNP) | VAF 23/383 reads (6%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); called by muse, mutect2
- TEX13C | c.210C>A p.S70R | Missense Mutation (SNP) | VAF 10/165 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- TIMM44 | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 17/373 reads (5%) | called by muse, mutect2
- TLL1 | c.841C>A p.P281T | Missense Mutation (SNP) | VAF 14/256 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.781); called by muse, mutect2
- TMEM204 | c.126C>A p.S42R | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- TMPRSS11E | c.893T>A p.L298H | Missense Mutation (SNP) | VAF 26/278 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TOR2A | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 3/36 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.069); called by muse, mutect2
- UNC45B | c.403G>T p.D135Y | Missense Mutation (SNP) | VAF 30/274 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- USH2A | c.15046G>T p.G5016* | Nonsense Mutation (SNP) | VAF 18/424 reads (4%) | called by muse, mutect2
- UTP20 | c.723_724insG p.C242Vfs*18 | Frame Shift Ins (INS) | VAF 6/38 reads (16%) | called by mutect2, varscan2
- VCAN | c.1187C>A p.P396H | Missense Mutation (SNP) | VAF 10/210 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); called by muse, mutect2
- VCAN | c.4095T>A p.H1365Q | Missense Mutation (SNP) | VAF 12/82 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WDR87 | c.3925G>A p.V1309I | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.106); called by muse, mutect2
- WRN | c.68A>T p.N23I | Missense Mutation (SNP) | VAF 20/288 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.439); called by muse, mutect2
- XPNPEP3 | c.500G>T p.R167L | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF772 | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.388); called by muse, mutect2
- ZNF804A | c.2200C>A p.Q734K | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.039); called by muse, mutect2
- ZXDA | c.1654A>G p.K552E | Missense Mutation (SNP) | VAF 19/522 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.283); called by muse, mutect2
- ADAM32 | c.972A>T p.A324= | Silent (SNP) | VAF 13/256 reads (5%) | called by muse, mutect2
- ANKLE1 | c.564G>A p.R188= (on ENST00000394458; = p.R134= on NM_152363.6) | Silent (SNP) | VAF 30/303 reads (10%) | called by muse, mutect2
- ARHGEF37 | c.1449A>T p.P483= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, varscan2
- C19orf18 | c.279G>T p.R93= | Silent (SNP) | VAF 10/118 reads (8%) | catalogued as rs1447600430, COSV58707518; called by muse, mutect2
- C3 | c.1266C>A p.I422= | Silent (SNP) | VAF 12/236 reads (5%) | called by muse, mutect2
- CACNG7 | c.102G>T p.L34= | Silent (SNP) | VAF 27/374 reads (7%) | catalogued as rs200628435; called by muse, mutect2
- CCSER1 | c.1137A>G p.L379= | Silent (SNP) | VAF 8/115 reads (7%) | called by muse, mutect2
- CHCHD2 | c.87A>T p.A29= | Silent (SNP) | VAF 15/246 reads (6%) | called by muse, mutect2
- CLCN7 | c.228A>T p.P76= | Silent (SNP) | VAF 40/433 reads (9%) | catalogued as rs1179249490; called by muse, mutect2, varscan2
- COL14A1 | c.1014G>T p.V338= | Silent (SNP) | VAF 10/174 reads (6%) | called by muse, mutect2
- COL4A1 | c.2025A>T p.P675= | Silent (SNP) | VAF 26/350 reads (7%) | called by muse, mutect2
- DCAF4 | c.633G>T p.T211= | Silent (SNP) | VAF 16/324 reads (5%) | catalogued as COSV100610973; called by muse, mutect2
- DGKG | c.1359G>T p.R453= | Silent (SNP) | VAF 24/394 reads (6%) | called by muse, mutect2
- DISC1 | c.96G>T p.A32= | Silent (SNP) | VAF 54/396 reads (14%) | catalogued as rs374290063; called by muse, mutect2, varscan2
- DLGAP2 | c.1110C>T p.S370= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as rs1178117809; called by muse, mutect2
- DOCK2 | c.2712C>A p.T904= | Silent (SNP) | VAF 43/257 reads (17%) | called by muse, mutect2, varscan2
- FAM71E2 | c.2052C>T p.S684= | Silent (SNP) | VAF 3/41 reads (7%) | called by muse, mutect2
- FAT4 | c.4317C>A p.V1439= | Silent (SNP) | VAF 12/150 reads (8%) | catalogued as rs754845367; called by muse, mutect2
- FAT4 | c.13461G>T p.A4487= | Silent (SNP) | VAF 19/162 reads (12%) | catalogued as COSV58671097; called by muse, mutect2, varscan2
- FLG | c.5934C>A p.G1978= | Silent (SNP) | VAF 44/596 reads (7%) | catalogued as rs541586017, COSV64240782; called by muse, mutect2
- GMEB1 | c.1315C>T p.L439= | Silent (SNP) | VAF 13/156 reads (8%) | catalogued as rs1447056402; called by muse, mutect2
- HEPH | c.3381T>A p.G1127= (on ENST00000343002; = p.G860= on NM_014799.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/490 reads (4%) | called by muse, mutect2
- IGF2R | c.4576C>T p.L1526= | Silent (SNP) | VAF 24/312 reads (8%) | catalogued as rs376385502; called by muse, mutect2
- IGFL1 | c.21C>T p.I7= | Silent (SNP) | VAF 14/236 reads (6%) | catalogued as rs985253916; called by muse, mutect2
- IRX2 | c.1386G>T p.V462= | Silent (SNP) | VAF 34/238 reads (14%) | called by muse, mutect2, varscan2
- KCNJ5 | c.510C>T p.V170= | Silent (SNP) | VAF 28/303 reads (9%) | called by muse, mutect2
- KRT83 | c.975G>A p.E325= | Silent (SNP) | VAF 42/626 reads (7%) | called by muse, mutect2
- MEIS1 | c.705C>T p.G235= | Silent (SNP) | VAF 44/474 reads (9%) | catalogued as rs1378768148; called by muse, mutect2
- NRXN3 | c.1284C>A p.T428= (on ENST00000335750 / NM_001330195.2; = p.T55= on NM_004796.6) | Silent (SNP) | VAF 15/162 reads (9%) | called by muse, mutect2
- OR51B2 | c.633C>A p.I211= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV60917063; called by muse, mutect2
- OR52E4 | c.507A>T p.P169= | Silent (SNP) | VAF 23/254 reads (9%) | called by muse, mutect2
- PCDHA3 | c.1440G>T p.R480= | Silent (SNP) | VAF 49/521 reads (9%) | called by muse, mutect2
- PDILT | c.1125A>G p.Q375= | Silent (SNP) | VAF 14/176 reads (8%) | catalogued as rs922915925; called by muse, mutect2
- PLXND1 | c.609G>T p.G203= | Silent (SNP) | VAF 5/52 reads (10%) | called by muse, mutect2
- SALL3 | c.777C>A p.P259= | Silent (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- SLC12A2 | c.1992A>T p.G664= | Silent (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- SLC16A9 | c.630A>G p.K210= | Silent (SNP) | VAF 12/148 reads (8%) | called by muse, mutect2
- SLC22A25 | c.345C>T p.P115= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV100123635, COSV60596337; called by muse, mutect2
- SLC8B1 | c.315C>T p.S105= | Silent (SNP) | VAF 6/110 reads (5%) | called by muse, mutect2
- SVEP1 | c.7431C>T p.T2477= | Silent (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- SYTL5 | c.477C>A p.T159= | Silent (SNP) | VAF 25/258 reads (10%) | catalogued as COSV52905600; called by muse, mutect2, varscan2
- TENM2 | c.6297C>A p.R2099= (on ENST00000518659 / NM_001122679.2; = p.R1860= on NM_001080428.3) | Silent (SNP) | VAF 16/206 reads (8%) | called by muse, mutect2
- USP17L7 | c.171T>C p.P57= | Silent (SNP) | VAF 64/790 reads (8%) | called by muse, mutect2
- ZNF536 | c.1278G>C p.L426= | Silent (SNP) | VAF 7/86 reads (8%) | catalogued as COSV100834514; called by muse, mutect2
- CEP126 | c.507-2331A>T | Intron (SNP) | VAF 8/68 reads (12%) | called by muse, mutect2
- COL12A1 | c.-1G>T | 5'UTR (SNP) | VAF 14/162 reads (9%) | called by muse, mutect2
- DHRS4-AS1 | n.2959C>T | RNA (SNP) | VAF 18/107 reads (17%) | called by muse, mutect2, varscan2
- DIPK2A | c.657+227C>A | Intron (SNP) | VAF 7/165 reads (4%) | called by muse, mutect2
- DPY19L2P2 | n.3120G>C | RNA (SNP) | VAF 10/260 reads (4%) | called by muse, mutect2
- DST | c.4297-3706A>G | Intron (SNP) | VAF 37/305 reads (12%) | catalogued as rs1336074594; ClinVar: likely benign; called by muse, mutect2, varscan2
- FBLN2 | c.*355C>A | 3'UTR (SNP) | VAF 19/294 reads (6%) | called by muse, mutect2
- FGFR3 | c.*2A>T | 3'UTR (SNP) | VAF 19/250 reads (8%) | called by muse, mutect2
- GUSBP10 | n.298G>A | RNA (SNP) | VAF 28/406 reads (7%) | catalogued as rs771936016; called by muse, mutect2
- GVINP1 | n.3902C>A | RNA (SNP) | VAF 17/157 reads (11%) | called by muse, mutect2, varscan2
- IGF2 | c.-4+158G>A | Intron (SNP) | VAF 8/162 reads (5%) | called by muse, mutect2
- KDM5C | c.*192G>T | 3'UTR (SNP) | VAF 16/128 reads (13%) | called by muse, mutect2, varscan2
- MIR551B | n.87G>T | RNA (SNP) | VAF 15/186 reads (8%) | called by muse, mutect2
- MPV17L2 | c.*180A>T | 3'UTR (SNP) | VAF 18/434 reads (4%) | called by muse, mutect2
- MYADML | n.1104C>A | RNA (SNP) | VAF 24/375 reads (6%) | called by muse, mutect2
- N4BP2L2 | c.1698-2330A>T | Intron (SNP) | VAF 10/142 reads (7%) | called by muse, mutect2
- NAV3 | c.2024-12895C>A | Intron (SNP) | VAF 11/162 reads (7%) | called by muse, mutect2
- NUCB2 | c.1255+11T>C | Intron (SNP) | VAF 17/181 reads (9%) | called by muse, mutect2, varscan2
- PRKAG1 | c.-30G>A | 5'UTR (SNP) | VAF 20/162 reads (12%) | catalogued as rs930207242; called by muse, mutect2
- PSD4 | c.1249+216G>T | Intron (SNP) | VAF 22/251 reads (9%) | called by muse, mutect2
- RNF217-AS1 | n.1118C>A | RNA (SNP) | VAF 9/116 reads (8%) | called by muse, mutect2
- SCAPER | c.2838+6843G>T | Intron (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- SLC17A4 | c.1120+23G>T | Intron (SNP) | VAF 18/215 reads (8%) | called by muse, mutect2
- TNNT3 | c.50-39A>T | Intron (SNP) | VAF 30/478 reads (6%) | called by muse, mutect2
- USP2-AS1 | n.196G>A | RNA (SNP) | VAF 23/280 reads (8%) | called by muse, mutect2
